Gene-level copy-number profile of tumor specimen TCGA-EB-A44R-06A from TCGA case TCGA-EB-A44R, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 53.7 years (19,601 days).
Specimen TCGA-EB-A44R-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.8890c4b4-29f4-40cf-a860-918a3ebb26ca.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EB-A44R-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/055034e0-19af-4a88-9751-01f1a4ec6705

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 418; copy number 2: 10,616; copy number 3: 20,061; copy number 4: 21,596; copy number 5: 721; copy number 6: 318; copy number 7: 3,215; copy number 8: 83; copy number 9: 48; copy number 10: 95; copy number 11: 1,964; copy number 12: 49; copy number 13: 86; copy number 14: 52; copy number 15: 3; copy number 16: 195; copy number 17: 37; copy number 18: 26; copy number 19: 28; copy number 20: 82; copy number 21: 60; copy number 26: 47; copy number 29: 3; copy number 33: 6; copy number 35: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EB-A44R-06A-41D-A25P-01): tumor purity 0.57, ploidy 3.76, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:80,527,960–81,431,520, 6 genes: RNU6-544P, ARL6IP1P3, LINC02720, AP003398.1, AP003398.2, AP003464.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,782 genes in 42 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:52,573,114–52,714,695, 6 genes, copy number 16: EEF1GP7, GPX7, SHISAL2A, COA7, NDUFS5P3, RN7SL62P.
- chr1:52,754,322–52,754,462, 1 gene, copy number 16: RNU2-30P.
- chr1:53,891,239–54,200,073, 15 genes, copy number 16 (within-gene range 3–16): DIO1, HSPB11, LRRC42, HNRNPA3P12, LDLRAD1, TMEM59, AL353898.3, TCEANC2, MIR4781, AL353898.1, AL353898.2, AL357673.1, CDCP2, AL357673.2, CYB5RL.
- chr1:61,248,945–63,660,245, 59 genes, copy number 9–20: NFIA-AS1, AC099791.3, AC099791.4, AC099791.1, TM2D1, AC099791.2, PATJ, RNU6-414P, RNU6-1177P, LAMTOR5P1, RN7SL180P, MIR3116-1, MIR3116-2, PIGPP2, RPS15AP7, L1TD1, AL162739.1, Y_RNA, KANK4, RNU6-371P, USP1, DOCK7, AL451044.1, ANGPTL3, AL138847.2, AL138847.1, AC103923.1, ATG4C, AC099794.1, AC099794.2, LINC01739, AL162400.3, AL162400.1, AL162400.2, AC096543.1, LINC00466, RNA5SP49, AC096543.2, RPSAP65, FOXD3-AS1, FOXD3, MIR6068, Y_RNA, AL049636.1, ALG6, ITGB3BP, BX004807.1, EFCAB7, RN7SL488P, RNU7-123P, DLEU2L, AL109925.3, AL109925.6, AL109925.4, AL109925.2, AL109925.5, AL109925.1, PGM1, RN7SL130P.
- chr1:63,788,721–63,789,304, 1 gene, copy number 13: AL161742.1.
- chr1:70,660,657–70,786,468, 3 genes, copy number 13: CASP3P1, LINC01788, AL513285.1.
- chr1:113,198,825–115,368,072, 44 genes, copy number 13–19: AL357055.2, MAGI3, AL391058.1, MTND5P20, PHTF1, AL133517.1, RSBN1, AL137856.1, PTPN22, AP4B1-AS1, BCL2L15, AP4B1, DCLRE1B, HIPK1-AS1, HIPK1, OLFML3, AL591742.1, AL591742.2, SYT6, AL121999.1, MRPL57P1, AL035410.2, TRIM33, AL035410.1, EIF2S2P5, Y_RNA, PKMP1, BCAS2, DENND2C, AMPD1, RN7SL432P, NRAS, CSDE1, RNY1P13, SIKE1, NR1H5P, SYCP1, TSHB, TSPAN2, LINC01765, AL049825.1, NGF-AS1, NGF, AL512638.3.
- chr1:115,976,513–208,270,667, 1,859 genes, copy number 9–21 (within-gene range 4–21) (broad region; genes not listed).
- chr1:243,256,034–248,919,946, 179 genes, copy number 11 (broad region; genes not listed).
- chr5:58,198–1,551,710, 57 genes, copy number 10–14: AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1, CEP72, TPPP, AC026740.1, ZDHHC11B, BRD9P2, AC026740.2, ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT, MIR4457, CLPTM1L, AC026748.7, LINC01511, MTCO2P32, AC026748.3, SLC6A3, LPCAT1, MIR6075, AC091849.2.
- chr5:1,708,785–2,184,820, 15 genes, copy number 18: MIR4277, AC112176.1, MRPL36, NDUFS6, AC025183.1, LINC02116, AC025183.2, IRX4, IRX4-AS1, CTD-2194D22.4, AC126768.3, AC124852.1, AC126768.1, AC126768.2, Y_RNA.
- chr5:4,135,638–5,490,220, 23 genes, copy number 12: LINC02063, AC106799.3, AC106799.2, AC106799.1, AC010634.1, LINC02114, AC026719.1, AC026415.1, AC010451.3, AC010451.1, LINC01020, AC010451.2, LINC02121, RN7SKP73, CTD-2297D10.2, ADAMTS16, AC022424.1, ALG3P1, AC091978.1, MTCO1P30, MTCO2P30, MTCO1P31, ICE1.
- chr5:6,765,891–6,833,120, 1 gene, copy number 17 (within-gene range 1–17): LINC02236.
- chr5:6,827,853–7,219,291, 5 genes, copy number 17 (within-gene range 1–17): MIR4278, LINC02196, RN7SKP79, AC122710.1, RNA5SP176.
- chr5:7,830,378–8,366,437, 10 genes, copy number 11–33 (within-gene range 1–33): C5orf49, MTRR, FASTKD3, AC025174.1, RNU1-76P, AC116361.1, AC091941.1, AC091912.2, AC091912.1, AC091912.3.
- chr5:9,498,401–9,712,378, 7 genes, copy number 13: AC027335.2, SEMA5A-AS1, AC027335.1, SNHG18, SNORD123, AC026787.1, TAS2R1.
- chr5:10,225,507–10,269,918, 5 genes, copy number 11: ATPSCKMT, AC012640.1, CCT5, AC012640.4, AC012640.3.
- chr5:10,971,836–11,904,446, 1 gene, copy number 9 (within-gene range 1–15): CTNND2.
- chr5:12,297,399–12,804,363, 3 genes, copy number 21 (within-gene range 1–21): RNU6-679P, AC106771.1, LINC01194.
- chr5:13,553,654–14,699,850, 12 genes, copy number 14–29: NENFP3, AC016546.1, DNAH5, AC016576.1, TRIO, AC016549.1, OTULINL, AC010627.1, CCT6P2, EEF1A1P13, AC010491.1, OTULIN.
- chr5:15,935,182–16,465,800, 9 genes, copy number 21: MIR887, RNA5SP178, MARCHF11, MARCHF11-AS1, AC092335.1, NACAP6, LINC02150, AC020980.1, ZNF622.
- chr5:16,615,926–19,234,487, 64 genes, copy number 13–26 (broad region; genes not listed).
- chr5:22,580,225–22,580,819, 1 gene, copy number 18: GCNT1P2.
- chr5:23,951,348–24,271,863, 6 genes, copy number 16: C5orf17, AC026784.1, ADH5P5, Y_RNA, AC114930.1, AC010342.1.
- chr5:24,772,144–27,496,994, 30 genes, copy number 17: AC106821.2, BTG4P1, SNORD29, LINC02239, AC106821.1, Y_RNA, LINC02228, LINC02211, AC099499.2, AC099499.1, AC106754.1, AC106754.2, AC022140.1, AC022140.2, RNU6-374P, AC022418.1, MSNP1, AC113370.1, RNU4-43P, AC025475.1, AC025475.2, AC113347.1, AC113347.2, AC113347.3, AC113347.4, CCNB3P1, CDH9, RNU6-738P, PURPL, AC113355.1.
- chr5:29,070,496–32,110,932, 42 genes, copy number 9–14 (within-gene range 4–14): AC024589.2, AC024589.1, AC024589.3, AC112172.2, LINC02064, AC027345.1, UBL5P1, AC108082.1, AC010374.2, AC010374.1, RN7SKP207, AC018765.1, HPRT1P2, AC114300.1, AC099517.1, AC026433.1, RPL19P11, AC026421.1, AC113386.1, CDH6, DUX4L51, DROSHA, Y_RNA, C5orf22, AC022417.1, RNU6-363P, PDZD2, AC022447.2, AC022447.4, AC022447.5, AC022447.3, AC022447.1, AC022447.7, AC022447.6, RNU6-358P, AC010469.1, RNU6-760P, AC010469.2, RPL5P14, TPT1P5, AC025458.1, MIR4279.
- chr5:32,531,633–32,888,145, 5 genes, copy number 11 (within-gene range 4–11): SUB1, LINC02061, AC008766.1, NPR3, AC025459.1.
- chr5:32,947,443–33,026,025, 3 genes, copy number 11: LINC02120, AC034223.1, AC034223.2.
- chr7:70,972–12,403,941, 233 genes, copy number 10–20 (broad region; genes not listed).
- chr7:13,854,355–14,974,777, 8 genes, copy number 13–21 (within-gene range 7–21): AC005019.2, AC005019.1, ETV1, Y_RNA, RPL6P21, DGKB, EEF1A1P26, AC006150.1.
- chr7:15,200,317–16,581,568, 14 genes, copy number 12 (within-gene range 6–12): AGMO, MEOX2, AC005550.2, LINC02587, AC005550.1, RPL36AP26, AC006041.2, AC006041.1, CRPPA, RPL36AP29, CRPPA-AS1, SOSTDC1, AC005014.3, LRRC72.
- chr7:17,374,867–19,773,617, 23 genes, copy number 10–18 (within-gene range 6–18): AC019117.2, AC019117.1, AC006482.1, SNX13, AC080080.1, RNMTL1P2, AC080080.2, PRPS1L1, HDAC9, MIR1302-6, AC010082.1, RN7SKP266, HDAC9-AS1, NPM1P13, TWIST1, AC003986.2, AC003986.3, AC003986.1, FERD3L, AC007091.1, POLR1F, MIR3146, TMEM196.
- chr7:20,217,577–20,331,747, 3 genes, copy number 13: AC005083.1, AC099342.1, AC004130.2.
- chr7:22,118,236–22,357,154, 2 genes, copy number 13 (within-gene range 7–13): RAPGEF5, RNA5SP227.
- chr7:25,134,692–25,326,865, 8 genes, copy number 10 (within-gene range 3–10): C7orf31, AC004129.2, AC004129.1, NPVF, AC004129.3, U3, TSEN15P3, AC003985.1.
- chr7:35,715,032–35,972,587, 9 genes, copy number 16–19: AC018647.1, SEPTIN7-DT, AC007551.1, SEPTIN7, AC007551.2, RNU6-1085P, AC087072.1, SEPTIN7P3, PPP1R14BP4.
- chr7:36,389,821–36,504,513, 2 genes, copy number 13: ANLN, AC006960.2.
- chr7:36,854,361–37,449,249, 4 genes, copy number 9–35 (within-gene range 3–35): ELMO1, MIR1200, ELMO1-AS1, RPS17P13.
- chr7:40,964,667–41,779,388, 4 genes, copy number 11–17: LINC01450, LINC01449, INHBA, INHBA-AS1.
- chr7:44,962,662–45,076,469, 4 genes, copy number 16 (within-gene range 3–16): MYO1G, SNHG15, SNORA9, CCM2.

Autosomal genes at a single copy (total copy number 1): 125. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
